Surgical pathology report (de-identified scan), TCGA case TCGA-19-4065, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-4065-01A (Primary Tumor).

SURGICAL PATHOLOGY

Date of Procedure:

DOB/Sex:

/ M

Date Received:

FINAL DIAGNOSIS

A. RIGHT BRAIN AND B. BRAIN TUMOR, BIOPSY AND EXCISION:
--GLIOBLASTOMA MULTIFORME (WHO GRADE IV).

Electronically Signed Out By

By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consult Diagnosis

A. touch imprint and microscopic: Glioblastoma.

Clinical History:

Right brain tumor

Specimens Submitted As:

A:R BRAIN BX
B: BRAIN TUMOR

Gross Description:

A. Received fresh, for intraoperative consult, labeled with the patient's name, Hospital number and "right brain tumor biopsy", is a white-pink soft tissue fragment, 0.5 x 0.5 x 0.5 cm. Touch imprint was performed. Portion of the specimen was frozen for intraoperative diagnosis. The specimen is entirely submitted in two cassettes.

B: Received in formalin, labeled with the patient's name and number, are multiple light tan to red-brown irregular soft tissue fragments measuring 2.3 x 1.5 x 0.5 cm in aggregate. Submitted in toto in one cassette.

Summary of cassettes:

A	1FS	frozen section
	2	remainder of the specimen

Source: NCI Genomic Data Commons file a0bf2543-8b34-4f56-869d-8cb738757d2a (TCGA-19-4065.E3EB10CD-611E-4424-8F2F-E771156168E0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).